Somatic mutation profile of tumor specimen C3N-02015-01 (aliquot CPT0115350009) from CPTAC case C3N-02015, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.6 years (19,939 days).
Specimen C3N-02015-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69fe2c36-1e4e-4958-a55b-89a5122bd6c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02015-31 (Blood Derived Normal), aliquot CPT0116350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc7f15bd-6ddf-4a9b-b941-97b49420fda6

The open-access MAF lists 73 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Intron 6, Frame Shift Del 5, Nonsense Mutation 2, 5'UTR 2, 3'Flank 1, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 65/276 reads (24%) | catalogued as rs1553645146, COSV56238008; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CD5L | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 116/464 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs756639840; called by muse, mutect2, varscan2
- H3C13 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 82/556 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as rs587737208, COSV58944016; called by mutect2, varscan2
- HYDIN | c.7264A>T p.R2422W | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV59264191; called by muse, mutect2, varscan2
- LAMB1 | c.4562T>C p.I1521T | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs199646967, COSV55968262; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MECOM | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV72110062; called by muse, mutect2, varscan2
- MECOM | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV72110006; called by muse, mutect2, varscan2
- NLGN4Y | c.1658G>T p.R553L | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1569381051, COSV59300341; called by muse, mutect2, varscan2
- PCDH17 | c.1446C>A p.H482Q | Missense Mutation (SNP) | VAF 94/503 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV64975059; called by muse, mutect2, varscan2
- PLPPR4 | c.2224A>G p.N742D | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs772023785, COSV64567633; called by muse, mutect2, varscan2
- RYR2 | c.8741C>T p.T2914M | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as rs766484260, COSV100773420; called by muse, mutect2, varscan2
- VPS13B | c.6131A>G p.N2044S | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs534471615, COSV62154832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA4 | c.6466C>T p.H2156Y | Missense Mutation (SNP) | VAF 96/510 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- AFTPH | c.1217T>C p.L406S | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATAD5 | c.1124_1125del p.E375Gfs*14 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.1042C>A p.L348I (on ENST00000392017 / NM_030803.7; = p.L329I on NM_017974.4) | Missense Mutation (SNP) | VAF 40/273 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GNT9 | c.406C>A p.R136S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CBX7 | c.736G>C p.D246H | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CCDC14 | c.913G>A p.D305N (on ENST00000488653; = p.D257N on NM_022757.5) | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CCDC150 | c.2751G>A p.K917= | Splice Region (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- DTX3L | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ESRP2 | c.694T>C p.Y232H | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- EXO1 | c.2487G>T p.E829D | Missense Mutation (SNP) | VAF 65/331 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGGY | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GSDMB | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- H3C13 | c.260del p.S87Tfs*4 | Frame Shift Del (DEL) | VAF 79/553 reads (14%) | called by mutect2, varscan2
- IGF2R | c.1186G>C p.G396R | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPRIPL1 | c.1633A>C p.T545P (on ENST00000439118 / NM_001008949.3; = p.T553P on NM_178495.6) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- KCND1 | c.1428G>T p.Q476H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KDELR2 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- MAML3 | c.1367del p.A456Vfs*66 | Frame Shift Del (DEL) | VAF 74/393 reads (19%) | called by mutect2, pindel, varscan2
- MAP2 | c.3757G>T p.D1253Y | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MROH7 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAALAD2 | c.1787del p.N596Tfs*17 | Frame Shift Del (DEL) | VAF 32/171 reads (19%) | called by mutect2, pindel, varscan2
- NKTR | c.1639A>T p.S547C | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- NOL6 | c.1321_1323del p.A441del | In Frame Del (DEL) | VAF 35/252 reads (14%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.8540T>A p.L2847* | Nonsense Mutation (SNP) | VAF 56/292 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA8 | c.148_149insCAATTCTGTG p.E50Afs*4 | Frame Shift Ins (INS) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- PRICKLE1 | c.1744A>G p.T582A | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRIM2 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RFX8 | c.1211A>G p.E404G (on ENST00000646446; = p.E333G on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC46A1 | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- SPAG17 | c.619A>T p.T207S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- SUGP1 | c.1715_1733del p.K572Tfs*15 | Frame Shift Del (DEL) | VAF 20/186 reads (11%) | called by mutect2, pindel, varscan2
- TAF15 | c.1514G>T p.R505L (on ENST00000605844 / NM_139215.3; = p.R502L on NM_003487.4) | Missense Mutation (SNP) | VAF 66/394 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TLN2 | c.3895G>A p.D1299N | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.901); called by muse, mutect2
- TNP2 | c.68G>C p.S23T | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- TRIM41 | c.1625A>G p.Q542R | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TTBK2 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 95/457 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF626 | c.109T>C p.Y37H | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- AP2A2 | c.918T>C p.N306= | Silent (SNP) | VAF 52/268 reads (19%) | catalogued as rs746936335; called by muse, mutect2, varscan2
- KCNJ9 | c.1062C>T p.P354= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2
- MAML2 | c.1881A>G p.Q627= | Silent (SNP) | VAF 143/717 reads (20%) | catalogued as rs1157850795; called by muse, mutect2, varscan2
- PDIA4 | c.453C>T p.Y151= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as rs770320537, COSV99036037; called by muse, mutect2
- PSMA7 | c.543T>C p.I181= | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as rs1326440744; called by muse, mutect2, varscan2
- PTPRB | c.1317A>T p.V439= | Silent (SNP) | VAF 50/277 reads (18%) | called by muse, mutect2, varscan2
- RBBP6 | c.3153A>G p.R1051= | Silent (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- ROBO3 | c.819C>A p.A273= | Silent (SNP) | VAF 72/406 reads (18%) | called by muse, mutect2, varscan2
- RSU1 | c.12T>A p.S4= | Silent (SNP) | VAF 43/226 reads (19%) | called by muse, mutect2, varscan2
- RUNX3 | c.177G>T p.L59= | Silent (SNP) | VAF 46/278 reads (17%) | called by muse, mutect2, varscan2
- SLC6A2 | c.1092C>T p.I364= | Silent (SNP) | VAF 112/504 reads (22%) | catalogued as COSV54921686; called by muse, mutect2, varscan2
- USP6 | c.3639C>T p.G1213= | Silent (SNP) | VAF 65/399 reads (16%) | called by muse, mutect2, varscan2
- WDFY4 | c.1983C>G p.L661= | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as rs760113841, COSV57444726; called by muse, mutect2
- WNT3 | c.426C>T p.D142= | Silent (SNP) | VAF 61/349 reads (17%) | called by muse, mutect2, varscan2
- ACSL4 | c.-318C>A | 5'UTR (SNP) | VAF 62/155 reads (40%) | called by muse, mutect2, varscan2
- AFAP1 | c.-3+50T>C | Intron (SNP) | VAF 80/358 reads (22%) | called by muse, mutect2, varscan2
- CBX2 | c.288+204C>T | Intron (SNP) | VAF 34/152 reads (22%) | called by muse, mutect2, varscan2
- CERS5 | c.872+230dup | Intron (INS) | VAF 20/113 reads (18%) | catalogued as rs1190038216; called by mutect2, pindel, varscan2
- FAM153CP | n.365-18T>A | Intron (SNP) | VAF 51/336 reads (15%) | called by muse, mutect2, varscan2
- FRYL | c.-67C>T | 5'UTR (SNP) | VAF 18/154 reads (12%) | called by muse, varscan2
- MTX1 | chr1:155215603 G>C | 3'Flank (SNP) | VAF 97/533 reads (18%) | called by muse, mutect2, varscan2
- RPL13A | c.88+13T>A | Intron (SNP) | VAF 67/304 reads (22%) | called by muse, mutect2, varscan2
- SORBS1 | c.2128+1082C>T | Intron (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
